Surgical pathology report (de-identified scan), TCGA case TCGA-GV-A40E, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site BLN - Cleveland Clinic, specimen TCGA-GV-A40E-01A (Primary Tumor).

[page 1 of 2]
Results

SURGIC

Patient Info

Patient Name

Sex

DOB

Results

Specimen #:
Submitting Physician:

FINAL DIAGNOSIS

1. Urinary bladder, TURB - Invasive poorly differentiated urothelial carcinoma with focal squamous differentiation.
- Tumor invades muscularis propria (detrusor muscle).

COMMENT

Procedure: TURBT

Histologic Type: Urothelial (transitional cell) carcinoma with squamous differentiation

Associated Epithelial Lesions: None identified

Histologic Grade (Urothelial Carcinoma (WHO): High-grade

Adenocarcinoma and Squamous Cell Carcinoma: N/A

Tumor Configuration: Solid/nodule

Adequacy of Material for Determining Muscularis Propria Invasion:

Muscularis propria (detrusor muscle) present

Lymph-Vascular Invasion: Indeterminate

Microscopic Extent of Tumor: Tumor invades muscularis propria (detrusor muscle)

Additional Pathologic Findings:

- Cautery artifact
- Necrosis

ICD-O-3

Carcinoma, urothelial, NOS
8120/3

Site: bladder, NOS
C67.9

7-5-12 RD

(Electronic Signature)

SPECIMEN SUBMITTED

A: BLADDER TUMOR

CLINICAL DATA

BLADDER CA

GROSS DESCRIPTION

A. Received fresh labeled "bladder tumor" are multiple fragments of tan-pink rubbery soft tissue aggregating to 4.6 x 3.4 x 1.8 cm, and weighing 8.1 grams. The specimen is totally submitted in formalin in cassettes A1-A6.

11/20/12

[page 2 of 2]
Encounter Date: [REDACTED]

Patient ID #: [REDACTED]

DOB: [REDACTED] (Age: [REDACTED])

Date of Report: [REDACTED]

Date of Procedure: [REDACTED]

Date of Receipt: [REDACTED]

Submitted by: [REDACTED]

Location: [REDACTED]

Test performed by: [REDACTED]

Lab and Collection

SURGICAL PATHOLOGY (Order [REDACTED] - Lab and Collection Information)

Result History

SURGICAL PATHOLOGY (Order [REDACTED] - Order Result History Report)

Result Information

Result Date and Time

Status

Provider Status

Final result

Reviewed

MyChart Status:

This result is currently released to

Display Full Result Report

Display Order Report

Source: NCI Genomic Data Commons file 59cba69e-09cc-4e4a-bd49-6442f5734ef3 (TCGA-GV-A40E.45815B18-3A6E-4A3D-8D48-0F4653026DFD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).